Somatic mutation profile of tumor specimen TCGA-04-1357-01A (aliquot TCGA-04-1357-01A-01W-0492-08) from TCGA case TCGA-04-1357, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 52.0 years (18,999 days).
Specimen TCGA-04-1357-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20e45834-403d-4ce4-8ddf-1cef247423d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1357-11A (Solid Tissue Normal), aliquot TCGA-04-1357-11A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7a2ef72-d30e-491b-a9f6-63798e2b1a82

The open-access MAF lists 79 somatic variants for this specimen: 62 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 16, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.4612C>T p.Q1538* | Nonsense Mutation (SNP) | VAF 437/721 reads (61%) | catalogued as rs80356992, CM980230, COSV58785729; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.2917C>T p.Q973* | Nonsense Mutation (SNP) | VAF 10/240 reads (4%) | catalogued as COSV99427081; called by muse, mutect2
- ADCY1 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs566259707, COSV52031341; called by muse, mutect2, varscan2
- ALDH8A1 | c.820G>C p.A274P | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV55640579; called by muse, mutect2, varscan2
- ANK2 | c.5645C>T p.S1882L | Missense Mutation (SNP) | VAF 180/1052 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV52150006; called by muse, mutect2, varscan2
- ANK3 | c.7314G>C p.L2438F | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55047831; called by muse, mutect2
- ANKRD52 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 88/362 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57283011; called by muse, mutect2, varscan2
- ANPEP | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs148410109; called by muse, varscan2
- AP1M1 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV52225199; called by muse, mutect2, varscan2
- APC | c.1778G>T p.W593L | Missense Mutation (SNP) | VAF 148/780 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM970084, COSV57329332, COSV57330234; called by muse, mutect2, varscan2
- ARMC4 | c.2869G>C p.V957L | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.285); catalogued as COSV59458212; called by muse, mutect2, varscan2
- ARMC9 | c.1956G>C p.R652S | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV63019794; called by muse, mutect2, varscan2
- BLM | c.255G>T p.R85S | Missense Mutation (SNP) | VAF 256/797 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61922335; called by mutect2, varscan2
- CACNA1D | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV55440184, COSV55456071; called by muse, mutect2, varscan2
- CD22 | c.2373T>A p.D791E | Missense Mutation (SNP) | VAF 125/447 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV50050084; called by muse, mutect2, varscan2
- CES5A | c.777C>A p.Y259* | Nonsense Mutation (SNP) | VAF 33/964 reads (3%) | catalogued as COSV99307629; called by muse, mutect2
- CHRM2 | c.844A>T p.S282C | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100281410; called by muse, mutect2
- CLTCL1 | c.1177C>A p.R393S | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99595238; called by muse, varscan2
- COL6A6 | c.4626dup p.G1543Rfs*33 | Frame Shift Ins (INS) | VAF 12/86 reads (14%) | catalogued as rs746783819; called by mutect2, varscan2
- FOLR2 | c.600C>A p.S200R | Missense Mutation (SNP) | VAF 94/390 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53351186; called by muse, mutect2, varscan2
- GFOD2 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs566819045, COSV52057220; called by muse, mutect2, varscan2
- HEPACAM2 | c.460C>G p.H154D (on ENST00000394468 / NM_001039372.4; = p.H142D on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV59058322; called by muse, mutect2, varscan2
- KCTD20 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54802460; called by muse, mutect2, varscan2
- MAP1B | c.4016C>G p.S1339C | Missense Mutation (SNP) | VAF 29/981 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1439654318, COSV99702471; called by muse, mutect2
- MASP1 | c.1086T>A p.C362* | Nonsense Mutation (SNP) | VAF 361/1045 reads (35%) | catalogued as COSV99397259; called by muse, mutect2, varscan2
- MCOLN3 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100352783; called by muse, mutect2
- MRPL10 | c.376T>C p.F126L | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV51619502; called by muse, mutect2, varscan2
- MYH1 | c.3506A>C p.K1169T | Missense Mutation (SNP) | VAF 203/357 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56844797; called by muse, mutect2, varscan2
- NCAN | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53047718; called by muse, mutect2, varscan2
- OR52N4 | c.113T>A p.V38D | Missense Mutation (SNP) | VAF 77/393 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV57890494, COSV57893265; called by muse, mutect2, varscan2
- OR5W2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs750353731, COSV60614549, COSV60616410; called by muse, mutect2, varscan2
- PIKFYVE | c.3898G>A p.D1300N | Missense Mutation (SNP) | VAF 115/912 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); catalogued as COSV52238048; called by mutect2, varscan2
- PPP1R12B | c.1301C>G p.S434C | Missense Mutation (SNP) | VAF 99/454 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61114142; called by muse, varscan2
- PTPN4 | c.316A>G p.R106G | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99750394; called by muse, mutect2
- PXDN | c.3534T>G p.N1178K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99413752; called by muse, mutect2, varscan2
- SAMD3 | c.984C>G p.D328E | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV63713629; called by muse, mutect2, varscan2
- SEC16B | c.2899C>G p.L967V | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV57624069; called by muse, mutect2, varscan2
- SERTAD4 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 21/484 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as COSV100882627; called by muse, mutect2
- SFTPA1 | c.336C>G p.H112Q | Missense Mutation (SNP) | VAF 313/811 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100957038; called by muse, mutect2, varscan2
- SLC16A14 | c.254T>G p.I85R | Missense Mutation (SNP) | VAF 100/203 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54617251, COSV54618028; called by muse, mutect2, varscan2
- SLC22A12 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs763298510, CM088171, COSV60571207; called by muse, mutect2, varscan2
- SLC26A8 | c.2363T>A p.V788D | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100839488; called by muse, mutect2, varscan2
- SLC26A8 | c.2362G>C p.V788L | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100839490; called by muse, mutect2, varscan2
- SLC5A1 | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99833476; called by muse, mutect2
- SMG1 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV67169844; called by mutect2, varscan2
- SOGA1 | c.2038G>T p.G680C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV52911041; called by muse, mutect2
- STAT5B | c.1827C>G p.N609K | Missense Mutation (SNP) | VAF 223/439 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.058); catalogued as COSV53180974; called by muse, mutect2, varscan2
- SYNCRIP | c.1406A>G p.Y469C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as COSV62286990; called by muse, mutect2
- TAMM41 | c.709-1G>C p.X237_splice | Splice Site (SNP) | VAF 55/184 reads (30%) | catalogued as COSV56070903; called by muse, mutect2, varscan2
- TEX11 | c.1454G>A p.R485Q (on ENST00000344304; = p.R470Q on NM_031276.3) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1385768042, COSV100721809; called by muse, mutect2, varscan2
- TOP2A | c.3498G>T p.L1166F | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70732203; called by muse, mutect2, varscan2
- TP53 | c.669_670del p.E224Gfs*4 | Frame Shift Del (DEL) | VAF 46/147 reads (31%) | catalogued as COSV52796900; called by mutect2, pindel, varscan2
- TRIML1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 30/444 reads (7%) | catalogued as COSV100206048; called by muse, mutect2
- TTI1 | c.1785C>G p.I595M | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV65060784; called by muse, mutect2, varscan2
- VN1R5 | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 231/694 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1340358372; called by muse, varscan2
- WRN | c.1406A>G p.E469G | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV53296956; called by muse, mutect2, varscan2
- ZNF236 | c.2621C>G p.S874C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs778191974, COSV53483726; called by muse, mutect2, varscan2
- MICAL1 | c.1177del p.D393Tfs*28 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by pindel, varscan2
- NTRK3 | c.765+2_765+30del p.X255_splice | Splice Site (DEL) | VAF 91/422 reads (22%) | called by mutect2, pindel
- PLEKHG1 | c.2925_2946del p.R975Sfs*13 | Frame Shift Del (DEL) | VAF 37/143 reads (26%) | called by mutect2, pindel, varscan2
- SPATA18 | c.1274_1298del p.C425* | Frame Shift Del (DEL) | VAF 47/508 reads (9%) | called by mutect2, pindel
- TOP2A | c.462_477delinsAAAGAAAGTGACAG p.D154Efs*17 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by pindel, varscan2*
- AKAP12 | c.3762T>G p.T1254= | Silent (SNP) | VAF 212/429 reads (49%) | catalogued as COSV53571085; called by muse, mutect2, varscan2
- AL592490.1 | c.2004T>A p.A668= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV101308217; called by muse, mutect2, varscan2
- AURKA | c.975G>T p.G325= | Silent (SNP) | VAF 20/352 reads (6%) | catalogued as COSV100453041; called by muse, mutect2
- BMP3 | c.678C>T p.R226= | Silent (SNP) | VAF 60/166 reads (36%) | catalogued as COSV51081962; called by muse, mutect2, varscan2
- GCN1 | c.2112G>A p.R704= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV56104854; called by muse, mutect2, varscan2
- HARS1 | c.1299T>C p.D433= | Silent (SNP) | VAF 54/184 reads (29%) | catalogued as COSV56905842; called by muse, mutect2, varscan2
- IGKV2D-30 | c.93G>A p.L31= | Silent (SNP) | VAF 18/60 reads (30%) | called by mutect2, varscan2
- MYH7 | c.3813C>T p.N1271= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs767389598, COSV62517184; called by muse, mutect2, varscan2
- PTPN14 | c.21C>T p.L7= | Silent (SNP) | VAF 193/714 reads (27%) | catalogued as COSV65282007; called by muse, mutect2, varscan2
- RANBP10 | c.873C>T p.S291= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as COSV58156380; called by muse, mutect2, varscan2
- SLC7A7 | c.723C>G p.G241= | Silent (SNP) | VAF 44/460 reads (10%) | catalogued as COSV53539634; called by muse, mutect2
- SYNE1 | c.15246C>T p.S5082= (on ENST00000367255 / NM_182961.4; = p.S5011= on NM_033071.3) | Silent (SNP) | VAF 9/176 reads (5%) | catalogued as COSV54934282, COSV99566956; called by muse, mutect2
- TMC2 | c.414G>A p.L138= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100727658; called by muse, mutect2
- UBE2L6 | c.405G>T p.L135= | Silent (SNP) | VAF 60/1239 reads (5%) | catalogued as COSV99761891; called by muse, mutect2
- XKR6 | c.945C>T p.S315= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs772794829, COSV58654812; called by muse, mutect2, varscan2
- YEATS2 | c.552T>A p.I184= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV59362685; called by muse, varscan2
- ZNF271P | n.1286G>A | RNA (SNP) | VAF 29/170 reads (17%) | catalogued as rs776405455; called by muse, mutect2, varscan2
